Gene-level copy-number profile of specimen HCM-CSHL-0085-C24-85M from HCMI case HCM-CSHL-0085-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 56.0 years (20,466 days).
Specimen HCM-CSHL-0085-C24-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5fd52c31-6064-41f7-8803-6d590a744f87.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0085-C24-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,867 have no estimate.
https://portal.gdc.cancer.gov/files/f2f99e9b-5a7f-466b-ab2a-4091a1d1ffe5

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 352; copy number 2: 3,808; copy number 3: 903; copy number 4: 41,902; copy number 5: 651; copy number 6: 7,743; copy number 7: 250; copy number 8: 3,018; copy number 9: 46; copy number 10: 48; copy number 13: 5; copy number 14: 26; copy number 15: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 129 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,461,221–144,068,350, 26 genes, copy number 14: AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D.
- chr11:55,602,360–55,666,195, 4 genes, copy number 9: OR4C11, OR4P4, OR4S2, OR4C6.
- chr12:102,809,280–102,960,513, 4 genes, copy number 9: LINC00485, PAH, AC026108.1, ASCL1.
- chr12:108,434,130–108,515,023, 1 gene, copy number 9: LINC01498.
- chr12:110,719,680–110,742,939, 1 gene, copy number 9: PPP1CC.
- chr12:127,462,507–127,463,197, 1 gene, copy number 9: AC068787.1.
- chr12:128,793,194–128,827,579, 3 genes, copy number 9: SLC15A4, AC108704.2, AC108704.1.
- chr12:131,292,068–131,299,751, 4 genes, copy number 15: RPS6P20, AC092850.1, LINC02415, RNA5SP376.
- chr12:132,332,005–133,238,549, 50 genes, copy number 9–10: AC148477.7, AC148477.8, AC148477.6, AC148477.9, AC148476.1, AC079031.1, AC079031.2, FBRSL1, AC131212.3, AC131212.2, MIR6763, AC131212.1, LRCOL1, P2RX2, AC131212.4, POLE, PXMP2, AC135586.2, PGAM5, RNA5SP379, ANKLE2, AC135586.1, GOLGA3, CHFR, RPS11P5, RNU6-327P, AC127070.4, AC127070.1, AC127070.3, AC127070.2, ZNF605, NANOGNBP2, ZNF26, RNU4ATAC12P, ZNF84-DT, PTP4A1P2, ZNF84, AC073911.1, AC073911.2, ZNF140, ZNF891, AC026786.2, RPL23AP67, ZNF10, AC026786.1, ZNF268, AC226150.1, ANHX, RNU6-717P, Y_RNA.
- chr21:7,744,962–8,701,562, 29 genes, copy number 9: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1.
- chr21:10,521,553–10,649,835, 5 genes, copy number 13 (within-gene range 8–13): TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1.
- chr22:36,189,124–36,204,840, 1 gene, copy number 9: APOL4.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
